Somatic mutation profile of tumor specimen TARGET-30-PAKZRF-01A (aliquot TARGET-30-PAKZRF-01A-01W) from TARGET case TARGET-30-PAKZRF, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 3.5 years (1,285 days).
Specimen TARGET-30-PAKZRF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccf47ea5-f746-48fa-acc9-1106a9ff72a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAKZRF-10A (Blood Derived Normal), aliquot TARGET-30-PAKZRF-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e138453-7873-4309-a7b1-dcff10fb32b7

The open-access MAF lists 36 somatic variants for this specimen: 28 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Frame Shift Ins 6, Silent 5, Nonsense Mutation 3, RNA 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYC | c.173C>T p.T58I (on ENST00000377970; = p.T73I on NM_002467.6) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756091827, COSV52367994, COSV52373588; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATG4C | c.892G>T p.G298C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58605346; called by muse, mutect2, varscan2
- C1orf210 | c.192C>A p.Y64* | Nonsense Mutation (SNP) | VAF 112/250 reads (45%) | catalogued as COSV70682472; called by muse, mutect2, varscan2
- CNNM4 | c.1551C>A p.D517E | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as COSV65660684; called by muse, mutect2, varscan2
- DIPK2A | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 134/382 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.758); catalogued as COSV59857195, COSV59858050; called by muse, mutect2, varscan2
- DLX6 | c.804dup p.N269Qfs*59 | Frame Shift Ins (INS) | VAF 12/137 reads (9%) | catalogued as rs1469158094; called by mutect2, pindel
- FLG | c.7422G>T p.Q2474H | Missense Mutation (SNP) | VAF 268/602 reads (45%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.97); catalogued as COSV64240854; called by muse, mutect2, varscan2
- HCFC1R1 | c.249dup p.M84Hfs*16 | Frame Shift Ins (INS) | VAF 13/65 reads (20%) | catalogued as rs746547303; called by mutect2, varscan2
- HOXB4 | c.353dup p.P119Afs*182 | Frame Shift Ins (INS) | VAF 9/79 reads (11%) | catalogued as rs1323181055; called by mutect2, pindel
- ITPR1 | c.5419C>G p.L1807V (on ENST00000354582; = p.L1752V on NM_002222.7) | Missense Mutation (SNP) | VAF 16/502 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs1323560841, COSV56973245; called by muse, mutect2
- LIMD1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56266956; called by muse, mutect2, varscan2
- MGAT5B | c.2055dup p.A686Rfs*27 (on ENST00000569840 / NM_001199172.2; = p.A684Rfs*27 on NM_144677.3) | Frame Shift Ins (INS) | VAF 12/110 reads (11%) | catalogued as rs781189214; called by mutect2, pindel
- MYH7 | c.5639G>T p.R1880L | Missense Mutation (SNP) | VAF 71/293 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV62518620, COSV62521242; called by muse, mutect2, varscan2
- NLGN1 | c.1750C>A p.L584I | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.425); catalogued as COSV64331258; called by muse, mutect2, varscan2
- OR8H1 | c.191C>A p.T64N | Missense Mutation (SNP) | VAF 141/906 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV57293832, COSV57296346; called by muse, mutect2, varscan2
- PTPN13 | c.334dup p.A112Gfs*2 | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | catalogued as rs762510393; called by pindel, varscan2
- RNF157 | c.1850A>G p.N617S | Missense Mutation (SNP) | VAF 170/1221 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV53943672; called by muse, mutect2, varscan2
- SCN4A | c.5077G>T p.E1693* | Nonsense Mutation (SNP) | VAF 48/353 reads (14%) | catalogued as rs1555600612, COSV71126034, COSV71126576; called by muse, mutect2, varscan2
- SDK2 | c.2236G>A p.D746N | Missense Mutation (SNP) | VAF 110/241 reads (46%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV66185045; called by muse, mutect2, varscan2
- SEH1L | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs1237893129, COSV50816641; called by muse, mutect2, varscan2
- SEZ6 | c.915dup p.P306Afs*2 | Frame Shift Ins (INS) | VAF 18/126 reads (14%) | catalogued as rs766332422; called by mutect2, varscan2
- TRIM6 | c.974T>C p.F325S | Missense Mutation (SNP) | VAF 214/489 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.107); catalogued as COSV53475788; called by muse, mutect2, varscan2
- CCDC30 | c.1504T>C p.Y502H (on ENST00000340612; = p.Y459H on NM_001080850.3) | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.1); called by muse, mutect2
- HYOU1 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MRM3 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2
- OR5B12 | c.332T>A p.F111Y | Missense Mutation (SNP) | VAF 37/530 reads (7%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2
- RPUSD3 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.019); called by muse, mutect2
- USP43 | c.2043G>A p.W681* | Nonsense Mutation (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- HCN1 | c.1182C>T p.T394= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as rs1261922847, COSV100302482, COSV57504508, COSV57532447; ClinVar: likely benign; called by muse, mutect2
- MINK1 | c.3945C>A p.G1315= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV53417691; called by muse, mutect2, varscan2
- SLC13A1 | c.1584C>A p.L528= | Silent (SNP) | VAF 11/264 reads (4%) | catalogued as COSV52008392; called by muse, mutect2
- TMED1 | c.369G>A p.L123= | Silent (SNP) | VAF 90/227 reads (40%) | catalogued as COSV53033642; called by muse, mutect2, varscan2
- ZNF48 | c.546G>C p.R182= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV60783011; called by muse, mutect2, varscan2
- DCHS2 | n.5550G>T | RNA (SNP) | VAF 11/200 reads (6%) | called by muse, mutect2
- SNORD116-26 | n.67T>C | RNA (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- TTN | c.34265-4500T>C | Intron (SNP) | VAF 8/163 reads (5%) | called by muse, mutect2
